CPTAC case C3L-04033 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b3c53319-899d-40dc-ae82-dd5742fad7ab

Demographics
Sex at birth: male; Race: white; Year of birth: 1979; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 39.2 years (14,325 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,405 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,405 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 4 cm); Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 10; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 489 days (1.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 854 days (2.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 993 days (2.7 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 993 days (2.7 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,405 days (3.8 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 78 kg; Height: 178 cm; BMI: 24.62; FEV1/FVC before bronchodilator (%): 84; FEV1 before bronchodilator (% of reference): 63.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04033-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 107 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04033-21: Section location: Right lung; Percent tumor nuclei: 75; Percent necrosis: 2.
- Sample C3L-04033-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 73 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04033-22: Section location: Right lung; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-04033-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 286 mg; Time between clamping and freezing: 31 minutes; Time between excision and freezing: 16 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-04033-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -8 days; Method of sample procurement: Blood Draw.
